Gene-level copy-number profile of tumor specimen TCGA-MT-A67D-01A from TCGA case TCGA-MT-A67D, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Anterior floor of mouth; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 55.8 years (20,386 days).
Specimen TCGA-MT-A67D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c1cecdaf-386a-4935-8dc1-32712ce50a65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MT-A67D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3cd7617c-0f45-486b-ae0d-bae312547fe6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 2: 11,545; copy number 3: 22,347; copy number 4: 22,069; copy number 5: 1,746; copy number 6: 103; copy number 7: 773; copy number 8: 772; copy number 9: 306; copy number 10: 82; copy number 15: 27; copy number 22: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MT-A67D-01A-31D-A30D-01): tumor purity 0.34, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,997 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr7:70,972–62,275,678, 1,079 genes, copy number 7–9 (broad region; genes not listed).
- chr8:36,277,763–39,310,443, 82 genes, copy number 10 (broad region; genes not listed).
- chr11:68,683,779–71,818,238, 91 genes, copy number 8–22 (within-gene range 2–22) (broad region; genes not listed).
- chr11:81,821,272–82,718,299, 1 gene, copy number 8 (within-gene range 2–8): MIR4300HG.
- chr11:82,603,529–83,423,516, 31 genes, copy number 8: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 8: DLG2-AS2, AP002370.1, LDHAL6DP.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
